Gene-level copy-number profile of tumor specimen TCGA-KK-A8IF-01A from TCGA case TCGA-KK-A8IF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-KK-A8IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e54e5efc-a723-4958-b98c-534eba6b563b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A8IF-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2128a357-a55f-42fd-a9fa-dac021a2d44a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 134; copy number 2: 5,420; copy number 3: 1,782; copy number 4: 39,047; copy number 5: 2,588; copy number 6: 8,836; copy number 7: 198; copy number 8: 315; copy number 9: 1,464; copy number 13: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A8IF-01A-11D-A363-01): tumor purity 0.97, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,886,688–51,932,036, 2 genes: RNA5SP182, KATNBL1P4.
- chr5:63,022,919–64,612,319, 10 genes: AC113420.1, AC025445.1, AC008558.1, HTR1A, AC122707.1, RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P.
- chr5:98,338,744–98,577,260, 6 genes: AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4.
- chr5:103,032,376–103,278,660, 5 genes: EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR.
- chr5:109,448,349–109,499,108, 4 genes: AC010625.1, AC091917.3, AC091917.2, AC091917.1.
- chr5:113,738,106–113,776,837, 1 gene: AC093240.1.
- chr5:166,382,305–166,382,599, 1 gene: AC026403.1.
- chr6:98,868,535–98,948,006, 1 gene (within-gene range 0–1): FBXL4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,468 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–84,947,061, 4 genes, copy number 13: LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr8:49,086,301–49,741,321, 6 genes, copy number 9 (within-gene range 2–9): AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1.
- chr8:51,257,688–52,460,959, 16 genes, copy number 9 (within-gene range 2–9): AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17.
- chr8:52,939,182–145,066,685, 1,438 genes, copy number 9 (broad region; genes not listed).
- chr16:60,346,478–60,499,364, 1 gene, copy number 9 (within-gene range 2–9): AC009081.2.
- chr16:60,486,819–60,523,250, 1 gene, copy number 9 (within-gene range 3–9): AC009081.1.
- chr16:62,596,372–62,808,706, 2 genes, copy number 9: AC009110.1, AC010546.1.

Autosomal genes at a single copy (total copy number 1): 134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
